Gene-level copy-number profile of tumor specimen REBC-ACCT-TTP1-A from REBC case REBC-ACCT, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACCT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d996825-03eb-462f-acfa-1fd02636caeb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACCT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/5f25abcd-ad5a-430f-9c4a-226d6a6152f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 264; copy number 2: 58,022; copy number 3: 112; copy number 5: 2; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,569–209,892, 1 gene, copy number 7: AC079779.1.
- chr9:126,860,665–126,885,878, 1 gene, copy number 5: ZBTB34.
- chr19:54,379,489–54,379,960, 1 gene, copy number 5: AC245884.4.

Autosomal genes at a single copy (total copy number 1): 264. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
